CGCI case BLGSP-71-30-00778 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e3b7bd1-9e1e-462a-a747-657a1bcbcc9c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 22 years; Vital status: Dead; Days to death: 94 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt-like lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 22.6 years (8,268 days); Year of diagnosis: 2002; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 91 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Neck; Sites of involvement: Neck / Tongue / Vertebrae.
   Pathology details: Bone marrow malignant cells: Yes; Tumor largest dimension diameter: 4.9 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: IVAC; Days to treatment start: 14 days; Days to treatment end: 38 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Etoposide + Ifosfamide + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 14 days; Days to treatment end: 38 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Initial disease status: Initial Diagnosis; Days to treatment start: 61 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; adjuvant Radiation Therapy, NOS; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Days to follow up: 90 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Blood; Days to recurrence: 90 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 91 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (Flow Cytometry): Negative.
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MIB1 (Flow Cytometry): Positive.
- MYC translocation (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 342 [Blood test normal range upper: 210].

Other clinical attributes
- Day 0: Weight: 103.3 kg; Height: 203 cm; BMI: 25.1.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00778-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00778-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), atypical morphology; Extranodal site involvement: 3; Extranodal involvment other: Tongue, Vertebrae (cervical and thoracic spine); Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 342; Immunophenotypic analysis method: Flow cytometry, not otherwise specified.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: peripheral blood; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Treatment type: Stem Cell Transplant; Stem cell transplantation: Autologous; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Cyclophosphamide, intravenous methotrexate, IVAC, methotrexate; Pharma adjuvant cycles count: 4.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00778-01A-01E-0001-01:
- % tumour: 90
